Gene-level copy-number profile of specimen HCM-WCMC-0505-C16-85A from HCMI case HCM-WCMC-0505-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.9 years (27,705 days).
Specimen HCM-WCMC-0505-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2e5e784f-3df6-4946-9bfa-4d8a8ed8b482.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0505-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,265 have no estimate.
https://portal.gdc.cancer.gov/files/a6b9d945-f5fa-475a-bab9-fe04c3affb08

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 37; copy number 2: 9,768; copy number 3: 33,245; copy number 4: 8,406; copy number 5: 2,758; copy number 6: 101; copy number 7: 1,579; copy number 8: 1,760; copy number 9: 204; copy number 10: 72; copy number 11: 1; copy number 12: 202; copy number 13: 17; copy number 14: 130; copy number 15: 13; copy number 16: 7; copy number 17: 6; copy number 18: 6; copy number 19: 10; copy number 22: 9; copy number 75: 27.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,043 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,432,204–120,434,052, 1 gene, copy number 7: PFN1P2.
- chr1:143,419,625–192,185,815, 1,354 genes, copy number 8 (broad region; genes not listed).
- chr1:192,246,708–192,367,285, 3 genes, copy number 8: AL513175.1, AL513175.2, RGS21.
- chr2:205,681,990–206,265,326, 24 genes, copy number 7–9: NRP2, AC007362.1, RN7SKP178, PPIAP68, AC007679.1, INO80D, Vault, Y_RNA, RPL27P8, AC007383.1, NDUFS1, AC007383.2, GCSHP3, EEF1B2, AC007383.3, snoZ196, SNORD51, SNORA41, GPR1, GPR1-AS, RN7SKP200, ATP5POP1, HMGN1P6, RN7SKP260.
- chr4:6,200,733–6,308,636, 4 genes, copy number 7: LINC02495, AC113615.1, WFS1, AC116317.1.
- chr7:66,376,044–68,724,048, 53 genes, copy number 7 (within-gene range 6–7): LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231.
- chr7:70,837,738–93,148,385, 341 genes, copy number 7–75 (broad region; genes not listed).
- chr11:69,425,690–74,398,433, 167 genes, copy number 7–22 (within-gene range 6–22) (broad region; genes not listed).
- chr11:74,485,580–74,498,533, 3 genes, copy number 9 (within-gene range 4–9): AP001372.4, LIPT2, AP001372.2.
- chr11:111,290,787–111,347,824, 3 genes, copy number 9: COLCA1, COLCA2, MIR4491.
- chr12:38,316,762–39,170,880, 9 genes, copy number 7: ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1.
- chr15:88,459,477–88,605,110, 7 genes, copy number 7: MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2, LINC01586.
- chr18:23,134,564–23,260,467, 1 gene, copy number 8 (within-gene range 5–8): CABLES1.
- chr18:23,257,164–23,260,354, 1 gene, copy number 8 (within-gene range 5–8): AC011731.1.
- chr19:27,638,483–28,879,176, 28 genes, copy number 7–14: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1.
- chr19:29,205,320–40,950,660, 469 genes, copy number 7–12 (broad region; genes not listed).
- chr19:43,996,896–45,478,828, 79 genes, copy number 8–9 (within-gene range 2–9) (broad region; genes not listed).
- chr19:57,571,566–58,605,223, 95 genes, copy number 7–9 (broad region; genes not listed).
- chr20:87,250–64,327,972, 1,401 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 37. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
